Gene-level copy-number profile of tumor specimen TARGET-40-PALFYN-01A from TARGET case TARGET-40-PALFYN, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.3 years (4,841 days).
Specimen TARGET-40-PALFYN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.b3479c73-68ba-5423-bb4b-649f234779e4.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PALFYN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 399 have no estimate.
https://portal.gdc.cancer.gov/files/c6773505-8f64-4065-8810-70715efde2aa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 564; copy number 1: 3,146; copy number 2: 24,318; copy number 3: 21,742; copy number 4: 7,613; copy number 5: 2,229; copy number 6: 539; copy number 7: 40; copy number 8: 23; copy number 10: 10.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:115,802,363–117,139,389, 1 gene (within-gene range 0–1): LSAMP.
- chr3:116,360,024–117,027,039, 11 genes: LSAMP-AS1, LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr3:175,059,361–175,369,621, 4 genes: EEF1B2P8, NAALADL2-AS3, NAALADL2-AS2, MIR4789.
- chr5:165,129,307–165,241,756, 2 genes: AC091973.1, LINC01938.
- chr7:78,486,530–78,487,028, 1 gene: AC007237.1.
- chr7:153,144,313–154,894,285, 12 genes (within-gene range 0–1): AC079809.1, LINC01287, AC073236.1, PAXBP1P1, AC005998.1, DPP6, AC005588.1, AC006019.3, AC006019.1, AC006019.2, AC024730.1, AC073336.1.
- chr9:21,966,929–22,214,672, 9 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr10:64,036,345–64,037,280, 1 gene: AC012558.1.
- chr14:79,072,132–79,249,023, 3 genes: AC026888.1, AC022469.1, AC022469.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,782 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:182,573,634–182,839,561, 9 genes, copy number 5: RNASEL, Metazoa_SRP, RGS16, LINC01686, RGS8, LINC01688, AL353778.1, NPL, AL355999.1.
- chr1:198,156,994–198,322,420, 2 genes, copy number 6: NEK7, PRR13P1.
- chr1:204,218,853–204,494,724, 8 genes, copy number 5 (within-gene range 3–5): PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B.
- chr2:210,477,682–211,105,732, 3 genes, copy number 6 (within-gene range 2–6): CPS1, CPS1-IT1, AC012491.1.
- chr2:218,382,029–218,453,295, 5 genes, copy number 5: SLC11A1, CTDSP1, AC021016.2, MIR26B, VIL1.
- chr4:21,949,015–23,193,740, 8 genes, copy number 6 (within-gene range 4–6): AC096719.1, RNU6-420P, ADGRA3, AC098583.1, AC098583.2, GBA3, CDC42P6, AC097512.1.
- chr4:83,796,436–84,299,189, 1 gene, copy number 5 (within-gene range 2–5): AC079160.1.
- chr5:3,357,264–19,142,346, 265 genes, copy number 5 (within-gene range 5–9) (broad region; genes not listed).
- chr6:43,671,202–48,068,689, 77 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:70,972–727,650, 21 genes, copy number 5 (within-gene range 4–5): AC093627.1, AC093627.6, AC093627.22, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC188616.1, AC226118.1, AC188617.1, AC188617.2, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1.
- chr7:2,679,522–4,269,000, 13 genes, copy number 5 (within-gene range 3–5): AMZ1, GNA12, AC006028.1, CARD11, CARD11-AS1, RN7SKP130, AC024028.1, AC073316.1, AC073316.2, SDK1-AS1, SDK1, AC092427.1, AC011284.1.
- chr7:9,981,516–32,943,176, 366 genes, copy number 5–7 (within-gene range 3–10) (broad region; genes not listed).
- chr8:62,110,524–99,877,580, 582 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).
- chr8:103,121,032–122,733,804, 182 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:129,748,196–130,443,674, 16 genes, copy number 5 (within-gene range 4–5): GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1.
- chr8:141,391,995–145,066,685, 179 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr10:105,534,659–105,534,765, 1 gene, copy number 6: RNU6-463P.
- chr12:28,564,678–28,825,831, 2 genes, copy number 6: AC084754.1, AC022081.1.
- chr14:105,526,583–106,875,071, 200 genes, copy number 5 (broad region; genes not listed).
- chr15:90,811,528–96,551,517, 119 genes, copy number 5 (broad region; genes not listed).
- chr17:7,717,354–10,259,232, 90 genes, copy number 5–7 (broad region; genes not listed).
- chr17:13,299,184–13,601,929, 3 genes, copy number 6: LINC02093, HS3ST3A1, MIR548H3.
- chr17:15,999,784–18,389,647, 118 genes, copy number 6–10 (within-gene range 3–10) (broad region; genes not listed).
- chr17:19,215,615–19,336,715, 1 gene, copy number 5 (within-gene range 3–5): EPN2.
- chr17:19,296,596–22,706,703, 163 genes, copy number 5 (broad region; genes not listed).
- chr18:14,137,710–15,330,282, 47 genes, copy number 5: FRG2LP, AC006557.2, NF1P5, ANKRD20A5P, RNU6-316P, RHOT1P1, AP005212.4, AP005212.2, CYP4F35P, AP005212.3, AP005212.1, TERF1P2, FEM1AP2, AP006261.1, LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.
- chr19:27,638,483–31,787,255, 81 genes, copy number 5–8 (broad region; genes not listed).
- chr19:37,728,586–38,370,943, 23 genes, copy number 5 (within-gene range 2–5): AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1, WDR87, SIPA1L3, AC008395.1, AC011465.1, AC011479.3, AC011479.2, RN7SL663P, DPF1, SPINT2, PPP1R14A, AC011479.1, AC011479.4, Y_RNA, YIF1B, C19orf33, KCNK6, CATSPERG.
- chr22:22,686,726–26,596,717, 197 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,145. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
